Somatic mutation profile of tumor specimen C3L-05331-54 (aliquot CPT0303460002) from CPTAC case C3L-05331, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 63.3 years (23,133 days).
Specimen C3L-05331-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee46321f-7fa7-4a91-9cca-c14e725f12c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05331-51 (Buccal Cell Normal), aliquot CPT0303580001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46cd8794-8287-4f5b-8a98-6aba319bdebf

The open-access MAF lists 8 somatic variants for this specimen: 8 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EME2 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.221); catalogued as rs149531255; called by muse, mutect2, varscan2
- MBTD1 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 74/180 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV64503503; called by muse, mutect2, varscan2
- CTAGE1 | c.1493C>A p.S498Y | Missense Mutation (SNP) | VAF 85/258 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- KCND3 | c.863C>T p.T288M | Missense Mutation (SNP) | VAF 107/242 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAST2 | c.293T>C p.L98S | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- MTOR | c.2449G>A p.V817I | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMC1A | c.2032_2034del p.K678del | In Frame Del (DEL) | VAF 239/320 reads (75%) | called by pindel, varscan2
- WT1 | c.1093_1103del p.T365Vfs*4 | Frame Shift Del (DEL) | VAF 180/466 reads (39%) | called by mutect2, varscan2
